Somatic mutation profile of tumor specimen TCGA-DD-A4NR-01A (aliquot TCGA-DD-A4NR-01A-11D-A30V-10) from TCGA case TCGA-DD-A4NR, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 85.9 years (31,386 days).
Specimen TCGA-DD-A4NR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c956a9c-7eee-4eda-9980-cea4225ab963.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A4NR-10A (Blood Derived Normal), aliquot TCGA-DD-A4NR-10A-01D-A30V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/009270e7-74ff-48ae-bf18-6b027cf83fdf

The open-access MAF lists 50 somatic variants for this specimen: 40 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 9, Frame Shift Del 5, Nonsense Mutation 2, Translation Start Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AATK | c.729C>A p.H243Q (on ENST00000326724 / NM_001080395.3; = p.H140Q on NM_004920.2) | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); catalogued as COSV58689400; called by muse, mutect2, varscan2
- ACVR2B | c.407T>C p.L136P | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as COSV61702668; called by muse, mutect2, varscan2
- ADCY10 | c.1165G>A p.G389R | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63241812; called by muse, mutect2
- ARID1A | c.4424A>C p.N1475T | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV61372282, COSV61380869; called by muse, mutect2, varscan2
- ASTN1 | c.986G>A p.R329K | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.12); catalogued as COSV56073562; called by muse, varscan2
- BMPER | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs1176480335, COSV51822839, COSV99032584; called by muse, mutect2, varscan2
- CAMK1D | c.41del p.K14Sfs*26 | Frame Shift Del (DEL) | VAF 35/195 reads (18%) | catalogued as rs1273699119; called by mutect2, varscan2
- CHD4 | c.4565C>T p.S1522L (on ENST00000357008 / NM_001363606.2; = p.S1535L on NM_001273.5) | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV58904196; called by muse, mutect2, varscan2
- EYA4 | c.1762G>A p.E588K (on ENST00000531901 / NM_001301013.1; = p.E582K on NM_004100.5) | Missense Mutation (SNP) | VAF 43/241 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62054760; called by muse, mutect2, varscan2
- FBXO15 | c.1241A>T p.D414V | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV54046422; called by muse, mutect2, varscan2
- GEMIN5 | c.781G>A p.G261R | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); catalogued as rs753962116, COSV53561767, COSV53565128; called by muse, mutect2, varscan2
- IL23A | c.313G>C p.G105R | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV57336141; called by muse, mutect2, varscan2
- JARID2 | c.443C>G p.S148C | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1240260518, COSV59191568; called by muse, mutect2, varscan2
- KRT13 | c.646G>C p.D216H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99877490; called by muse, mutect2
- LRIT1 | c.170T>C p.I57T | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV64513258; called by muse, mutect2
- MED23 | c.1931G>A p.C644Y | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63433578; called by mutect2, varscan2
- MRGBP | c.322C>A p.P108T | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV65111539; called by muse, mutect2, varscan2
- MYH1 | c.5750C>T p.A1917V | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV56851224; called by muse, mutect2, varscan2
- OR2AG2 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV100643145, COSV58455568; called by mutect2, varscan2
- OVCH1 | c.2781C>A p.Y927* | Nonsense Mutation (SNP) | VAF 13/85 reads (15%) | catalogued as COSV58964784; called by muse, mutect2, varscan2
- PCDHGA10 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs753942667, COSV53893105; called by muse, mutect2, varscan2
- PHLPP2 | c.3914C>A p.P1305H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100673801; called by mutect2, varscan2
- PSMD6 | c.362T>A p.L121Q | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as COSV99896192; called by muse, varscan2
- RPAP1 | c.2237A>G p.D746G | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100426964, COSV58540376; called by muse, mutect2, varscan2
- RUNX2 | c.161A>C p.Q54P | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.009); catalogued as COSV61842678; called by muse, mutect2, varscan2
- SEC24A | c.497G>T p.S166I | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV59748032; called by muse, mutect2, varscan2
- SLC22A8 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV60324627; called by muse, mutect2, varscan2
- SLC4A5 | c.1021A>T p.T341S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.242); catalogued as COSV61029262; called by muse, mutect2, varscan2
- SP7 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs758338010, COSV58191154; called by muse, mutect2, varscan2
- SPG7 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.062); catalogued as COSV51947787, COSV51951767; called by muse, mutect2
- TST | c.169T>C p.S57P | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.756); catalogued as COSV50765218; called by muse, mutect2
- UTP25 | c.1624A>G p.I542V | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.083); catalogued as COSV71966018; called by muse, mutect2, varscan2
- XKR6 | c.868C>A p.L290M | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58657213; called by muse, mutect2, varscan2
- ZNF197 | c.634C>T p.Q212* | Nonsense Mutation (SNP) | VAF 7/49 reads (14%) | catalogued as COSV100482218; called by mutect2, varscan2
- ZNF839 | c.1685T>G p.L562R (on ENST00000558850 / NM_001267827.1; = p.L678R on NM_018335.5) | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV51758026; called by mutect2, varscan2
- AR | c.526_528delinsT p.S176Lfs*4 | Frame Shift Del (DEL) | VAF 9/70 reads (13%) | called by pindel, varscan2*
- ATP13A2 | c.2244G>T p.M748I | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- CLCN5 | c.1416_1437del p.M473Tfs*32 | Frame Shift Del (DEL) | VAF 19/101 reads (19%) | called by mutect2, pindel, varscan2
- ITIH2 | c.902del p.P301Lfs*17 | Frame Shift Del (DEL) | VAF 23/132 reads (17%) | called by mutect2, varscan2
- SHCBP1L | c.114del p.T39Pfs*2 | Frame Shift Del (DEL) | VAF 11/59 reads (19%) | called by mutect2, pindel, varscan2
- AADAC | c.708A>G p.S236= | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as COSV51760026; called by muse, mutect2, varscan2
- CDS1 | c.447T>C p.F149= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as COSV55688728; called by muse, mutect2, varscan2
- DEPDC1 | c.480C>T p.G160= | Silent (SNP) | VAF 35/253 reads (14%) | catalogued as rs561724598, COSV63958547; called by muse, varscan2
- KCNAB2 | c.174G>A p.V58= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV99379481; called by muse, varscan2
- NEXMIF | c.4206T>C p.N1402= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV50043304; called by muse, mutect2, varscan2
- PITPNM1 | c.3057C>A p.G1019= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV54161016; called by muse, mutect2, varscan2
- PUS7 | c.1125T>C p.Y375= | Silent (SNP) | VAF 22/115 reads (19%) | catalogued as rs1402455916, COSV62677176; called by muse, mutect2, varscan2
- SALL1 | c.2559T>G p.S853= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV51759589; called by muse, mutect2, varscan2
- SPTB | c.4705C>T p.L1569= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV67632848; called by muse, mutect2, varscan2
- MYBPC1 | c.3413-1757C>T | Intron (SNP) | VAF 29/135 reads (21%) | catalogued as rs1351132907, COSV62254181; called by muse, mutect2, varscan2
